Surgical pathology report (de-identified scan), TCGA case TCGA-TQ-A7RH, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Sao Paulo, specimen TCGA-TQ-A7RH-01A (Primary Tumor).

ICD-O-3

Oligoastrocytoma, grade II
CCCF 938213

Site: Brain, supratentorial NOS
C71.0

4/2/13

Brain NOS
C71.9

AD 10/4/13

Nature of material: Brain
Received on:

Macroscopy:

Received five irregular structures of the brain, the largest measuring 5.5 x 4.0 x 2.0 cm, partially covered by meninge and presenting on the outer surface a jelly, brown and irregular lesion. Smaller structures together measure 3.0 x 2.5 x 0.5 cm.

Microscopy:

Histological sections stained with H & E sections show diffuse glial neoplasm with moderate and polymorphic cellularity, consisting sometimes of cells with clear cytoplasm that exhibit perinuclear halo, sometimes by cells with elongated nuclei, dense chromatin and eosinophilic cytoplasm. The nuclei show moderate pleomorphism. Examination shows multiple cells with minigemistocytic aspect and satellitosis of neoplastic cells in cortical neurons. A few areas of the neoplasm presents with dense cellularity, with sparse mitotic figures and steeper nuclear atypia, but no foci of microvascular proliferation. In these areas the CPI Ki-67 is about 5%. It is also observed, focal deposits of hemosiderin. Not observed foci of necrosis in the tumor. In areas of astrocytic pattern, there is overexpression of p53. The tumor shows predominant oligodendroglial pattern.

Diagnosis:

Resection product of brain lesion: Oligoastrocytoma with diffuse anaplastic foci, WHO grade II (ICD-O 9382/3)

Notes:

There are no criteria for grade III, although the greater CPI Ki-67 in some areas associated with nuclear atypia are highly suggestive of malignancy progression to higher degree of malignancy.

PROFESSIONAL PARTICIPANTS OF REPORT

Source: NCI Genomic Data Commons file f70914e2-caf7-4aa1-948d-9adac2fe837d (TCGA-TQ-A7RH.489D1069-B12F-4250-9FD0-BA5997ADAC8D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).